Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6951, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6951-01A (Primary Tumor).

[page 1 of 2]
SUPPLEMENTAL REPORT

COMMENT: Decalcified sections of the mandible reveal invasion by squamous carcinoma into the mandibular bone, as well as perineural invasion. The anterior and posterior margins of the mandible are free of tumor.

DIAGNOSIS

- (A) LEFT SUPRAOMOHYOID NECK DISSECTION:
METASTATIC MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA IN 2 OF 29
LEFT CERVICAL LYMPH NODES, WITHOUT UNEQUIVOCAL EXTRANODAL
EXTENSION (1/6 SUBMENTAL-SUBMAXILLARY; 1/12 MID JUGULAR;
0/4 SUBDIGASTRIC; 0/7 UPPER POSTERIOR CERVICAL).
salivary gland with atrophy and chronic inflammation, no tumor
present.
- (B) RIGHT SUPRAOMOHYOID NECK DISSECTION:
Eighteen right cervical lymph nodes, no tumor present
(0/3 submaxillary; 0/0 subdigastric; 0/11 mid jugular;
0/4 upper posterior cervical).
salivary gland, no tumor present.
- (C) DEEP MENTAL MARGIN:
Fibroadiopose tissue, skeletal muscle and peripheral nerve, no tumor
present.
- (D) ANTERIOR BUCCAL MARGIN:
Squamous mucosa, no tumor present.
- (E) LEFT PHARYNGEAL MARGIN:
Squamous mucosa, no tumor present.
- (F) RIGHT LATERAL FLOOR OF MOUTH:
Squamous mucosa, no tumor present.
- (G) SUBTOTAL GLOSSECTOMY, MANDIBLE AND FLOOR OF MOUTH:
DEEPLY INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA INVOLVING
BASE OF TONGUE, FLOOR OF MOUTH AND SUBMENTAL SUBCUTANEOUS TISSUE.
(SEE COMMENT)
LYMPHATIC AND PERINEURAL INVASION PRESENT.
Mandible, pending decalcification.

COMMENT

The tumor grossly measured 4.0 x 3.5 x 2.0 cm. Additional tissue sections of the mandible are pending. A supplemental report will be issued after completion of all studies.

[page 2 of 2]
SPECIMEN

- (A) LEFT SUPRAOMOHYOID NECK DISSECTION:
- (B) RIGHT SUPRAOMOHYOID NECK DISSECTION:
- (C) DEEP MENTAL MARGIN:
- (D) ANTERIOR BUCCAL MARGIN:
- (E) LEFT PHARYNGEAL MARGIN:
- (F) RIGHT LATERAL FLOOR OF MOUTH:
- (G) SUBTOTAL GLOSSECTOMY, MANDIBLE AND FLOOR OF MOUTH:
-

Source: NCI Genomic Data Commons file 5fce59ad-e60e-4ab5-9e96-6a598fe0a483 (TCGA-CV-6951.27BEF264-2C79-43B3-9602-CBB7C66C0453.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).